Somatic mutation profile of tumor specimen ALCH-B3AU-TTR1-A (aliquot ALCH-B3AU-TTR1-A-1-0-D-A85H-36) from ALCHEMIST case ALCH-B3AU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 52.0 years (18,980 days).
Specimen ALCH-B3AU-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b0ad3fc-f266-4676-85c7-345251c1b562.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3AU-NB1-A (Blood Derived Normal), aliquot ALCH-B3AU-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/34160d98-4278-41aa-9cf1-4e5ab81d845e

The open-access MAF lists 398 somatic variants for this specimen: 270 protein-altering or splice-affecting, 68 silent, 60 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 238, Silent 68, Intron 30, Nonsense Mutation 18, 3'UTR 10, 5'UTR 9, 5'Flank 6, Splice Site 5, Splice Region 3, 3'Flank 3, Translation Start Site 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STK11 | c.869T>C p.L290P | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057524439, CD134907; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.722C>G p.S241C | Missense Mutation (SNP) | VAF 39/178 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TUBB | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.577); catalogued as rs587777357, CM1212023; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB11 | c.2125G>A p.E709K | Missense Mutation (SNP) | VAF 23/226 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.036); catalogued as rs201800225; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABI3BP | c.880G>C p.E294Q | Missense Mutation (SNP) | VAF 14/191 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.587); catalogued as rs748373614; called by muse, mutect2
- AC013489.1 | c.1032C>G p.I344M | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1396656443; called by muse, mutect2, varscan2
- AMACR | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 29/266 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as COSV56874000; called by muse, mutect2, varscan2
- ANKRD11 | c.7168C>T p.Q2390* | Nonsense Mutation (SNP) | VAF 12/95 reads (13%) | catalogued as COSV56358865; called by muse, mutect2, varscan2
- APBB1 | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.95); catalogued as rs1290625702; called by muse, mutect2, varscan2
- ARHGEF10 | c.1221C>G p.I407M (on ENST00000398564; = p.I382M on NM_014629.4) | Missense Mutation (SNP) | VAF 59/401 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.572); catalogued as rs1194442135, COSV50671493; called by muse, mutect2, varscan2
- ATG2A | c.5242G>A p.V1748M | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs758140381; called by muse, mutect2, varscan2
- BAG5 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.237); catalogued as COSV54573041, COSV99914779; called by muse, mutect2, varscan2
- BMP5 | c.843C>G p.I281M | Missense Mutation (SNP) | VAF 52/318 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.411); catalogued as rs752637340, COSV100895997; called by muse, mutect2, varscan2
- BMP5 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 50/300 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs1177138023; called by muse, mutect2, varscan2
- BRCA1 | c.4573C>G p.Q1525E | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as CD129146, CM1413407; called by muse, mutect2, varscan2
- C14orf39 | c.151A>G p.I51V | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as COSV58781810; called by muse, mutect2, varscan2
- C1QTNF1 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.027); catalogued as rs766028634, COSV59264315; called by muse, mutect2, varscan2
- CASTOR2 | c.906C>G p.F302L | Missense Mutation (SNP) | VAF 28/256 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as rs1346430095; called by muse, mutect2, varscan2
- CCAR1 | c.43C>G p.Q15E | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.68); catalogued as COSV56269042, COSV56269630; called by muse, mutect2, varscan2
- CCDC77 | c.852G>C p.E284D | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.104); catalogued as COSV53472492; called by muse, mutect2, varscan2
- CCDC9B | c.688G>C p.E230Q | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV101233547; called by muse, mutect2, varscan2
- CCT8 | c.1394C>G p.S465C | Missense Mutation (SNP) | VAF 30/236 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54506247; called by muse, mutect2, varscan2
- CCZ1B | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.668); catalogued as COSV100367710; called by mutect2, varscan2
- CDKN2A | c.250G>C p.D84H | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM085316, CM990358, COSV58683210, COSV58683289, COSV58686242, COSV58694349; called by muse, mutect2, varscan2
- COQ6 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 59/411 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146408955; called by muse, mutect2, varscan2
- DDC | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 53/346 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs931702374, COSV63563602; called by muse, mutect2, varscan2
- DHX29 | c.1358C>T p.S453L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.668); catalogued as rs1390138923; called by muse, mutect2, varscan2
- DMRTA1 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.226); catalogued as rs1245209816; called by muse, mutect2, varscan2
- DPY19L3 | c.1446-1G>A p.X482_splice | Splice Site (SNP) | VAF 22/175 reads (13%) | catalogued as COSV60478461; called by muse, mutect2, varscan2
- DPYD | c.296C>T p.S99L | Missense Mutation (SNP) | VAF 54/311 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV60077071; called by muse, mutect2, varscan2
- DST | c.15256G>C p.D5086H (on ENST00000361203 / NM_001374722.1; = p.D2674H on NM_015548.5) | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV55026626; called by muse, mutect2, varscan2
- DSTYK | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV65685207; called by muse, mutect2, varscan2
- DUOXA2 | c.100C>G p.L34V | Missense Mutation (SNP) | VAF 62/240 reads (26%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.815); catalogued as rs1371612087; called by muse, mutect2, varscan2
- EDRF1 | c.937G>A p.E313K (on ENST00000356792 / NM_001202438.2; = p.E279K on NM_015608.2) | Missense Mutation (SNP) | VAF 122/363 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as COSV61763375; called by muse, mutect2, varscan2
- EI24 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs751419166, COSV54020202; called by muse, mutect2, varscan2
- EPPK1 | c.5951G>T p.G1984V | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV73262350; called by muse, mutect2, varscan2
- ERICH3 | c.3594C>A p.S1198R | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.023); catalogued as COSV100443958; called by muse, mutect2, varscan2
- ETV2 | c.422C>T p.S141L | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1435567426, COSV55837536, COSV55838312; called by muse, mutect2, varscan2
- FABP1 | c.146A>G p.K49R | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.069); catalogued as COSV55559204; called by muse, mutect2, varscan2
- FAM171A1 | c.1627C>T p.R543* | Nonsense Mutation (SNP) | VAF 22/68 reads (32%) | catalogued as COSV65313561; called by muse, mutect2, varscan2
- FANCC | c.489G>T p.E163D | Missense Mutation (SNP) | VAF 52/408 reads (13%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.793); catalogued as COSV56660348; called by muse, mutect2, varscan2
- FBLN2 | c.2526C>G p.I842M | Missense Mutation (SNP) | VAF 17/250 reads (7%) | SIFT tolerated (0.72); PolyPhen benign (0.02); catalogued as rs1489460628; called by muse, mutect2
- FER1L6 | c.934G>C p.E312Q | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67548489; called by muse, varscan2
- FLG | c.5611G>A p.E1871K | Missense Mutation (SNP) | VAF 55/364 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.204); catalogued as rs200306924, COSV64248908; called by muse, mutect2, varscan2
- FLG | c.3504C>A p.H1168Q | Missense Mutation (SNP) | VAF 86/272 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as rs766224121, COSV64253335; called by muse, mutect2, varscan2
- FZD6 | c.1859C>T p.S620L | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.042); catalogued as rs762588534, COSV62471436; called by muse, mutect2, varscan2
- GBP3 | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 37/210 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.404); catalogued as rs1357084373, COSV99352332; called by muse, mutect2, varscan2
- GBX1 | c.877C>G p.Q293E | Missense Mutation (SNP) | VAF 65/231 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV99881017; called by muse, mutect2, varscan2
- GCK | c.868G>C p.E290Q | Missense Mutation (SNP) | VAF 34/205 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as CM081278; called by muse, mutect2, varscan2
- GLDN | c.443G>A p.G148E | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1291075541; called by muse, mutect2, varscan2
- GNAZ | c.594G>C p.K198N | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV50738641; called by muse, mutect2
- GNLY | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs770339428; called by muse, mutect2, varscan2
- GOLGA4 | c.4920G>C p.L1640F | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62712854; called by muse, mutect2, varscan2
- GRIP1 | c.1879G>A p.D627N (on ENST00000359742 / NM_001379345.1; = p.D575N on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/253 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.803); catalogued as COSV54045109; called by muse, mutect2, varscan2
- GTSE1 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1253416584; called by muse, mutect2, varscan2
- INPP4A | c.320C>G p.S107C | Missense Mutation (SNP) | VAF 39/243 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs780855388; called by muse, mutect2, varscan2
- INTS8 | c.1268C>G p.S423* | Nonsense Mutation (SNP) | VAF 24/160 reads (15%) | catalogued as COSV58252572; called by muse, mutect2, varscan2
- KDR | c.794C>T p.S265L | Missense Mutation (SNP) | VAF 61/387 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs539911006, COSV55758376, COSV99819088; ClinVar: not provided; called by muse, mutect2, varscan2
- KIT | c.230A>G p.N77S | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs371353189; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LMBR1 | c.242C>G p.S81* | Nonsense Mutation (SNP) | VAF 42/218 reads (19%) | catalogued as rs1233438390; called by muse, mutect2, varscan2
- MAP3K10 | c.394G>C p.E132Q | Missense Mutation (SNP) | VAF 56/178 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV99455058; called by muse, mutect2, varscan2
- MED26 | c.1702G>A p.D568N | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54661584; called by muse, mutect2, varscan2
- MPP2 | c.667G>A p.A223T (on ENST00000461854 / NM_001278372.2; = p.A199T on NM_005374.5) | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.028); catalogued as rs1255356198, COSV52235929; called by muse, mutect2, varscan2
- MSLNL | c.2018C>G p.S673* | Nonsense Mutation (SNP) | VAF 30/190 reads (16%) | catalogued as COSV53499289; called by muse, mutect2, varscan2
- MUC1 | c.3373G>A p.E1125K (on ENST00000611571 / NM_001371720.1; = p.E136K on NM_002456.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/225 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0.316); catalogued as COSV100104536; called by muse, mutect2, varscan2
- MUC3A | c.8594G>C p.R2865P | Missense Mutation (SNP) | VAF 52/240 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.018); catalogued as COSV60221474; called by muse, mutect2, varscan2
- MYO18B | c.6937A>T p.I2313F | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.053); catalogued as rs758283941; called by muse, mutect2
- MYOM3 | c.2419G>A p.D807N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs369456651; called by mutect2, varscan2
- NEUROD1 | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766539353, COSV99716981; called by muse, mutect2
- NRDC | c.2236G>C p.E746Q | Missense Mutation (SNP) | VAF 22/225 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.706); catalogued as COSV61403723; called by muse, mutect2, varscan2
- NUDT18 | c.887C>G p.S296C | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs1333329281; called by muse, mutect2, varscan2
- NUGGC | c.2014G>A p.E672K | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.448); catalogued as rs374292249; called by muse, mutect2, varscan2
- PADI1 | c.662C>A p.S221Y | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.73); catalogued as COSV64938152; called by muse, mutect2, varscan2
- PANX1 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs1360256377; called by muse, mutect2, varscan2
- PCDHB13 | c.2241G>C p.Q747H | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.005); catalogued as COSV53399637; called by muse, mutect2
- PDE6B | c.2392G>C p.D798H | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs746471576, COSV99728316; called by muse, varscan2
- PEX1 | c.2296G>A p.D766N | Missense Mutation (SNP) | VAF 28/312 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs374010060; ClinVar: uncertain significance; called by muse, mutect2
- PODXL2 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0.021); catalogued as rs1449844076, COSV100686587; called by muse, mutect2, varscan2
- PRKAR1A | c.416C>A p.S139* | Nonsense Mutation (SNP) | VAF 30/272 reads (11%) | catalogued as COSV62236331; called by muse, mutect2, varscan2
- PSMD8 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs777509142, COSV53059450; called by muse, mutect2, varscan2
- RAB11FIP1 | c.2560C>T p.P854S | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.023); catalogued as COSV99770230; called by muse, mutect2, varscan2
- RAB11FIP1 | c.1166C>G p.S389C | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.333); catalogued as COSV54763818; called by muse, mutect2, varscan2
- RFX4 | c.1435G>A p.E479K (on ENST00000392842 / NM_213594.3; = p.E385K on NM_032491.6) | Missense Mutation (SNP) | VAF 26/217 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs765605097, COSV57572936; called by muse, mutect2, varscan2
- RPS6KC1 | c.2477C>T p.S826L | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as rs573814230; called by muse, mutect2, varscan2
- RYR1 | c.4205C>T p.P1402L | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as rs766135560; ClinVar: uncertain significance; called by muse, mutect2
- RYR2 | c.8536G>A p.E2846K | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV63688238; called by muse, varscan2
- SLC34A2 | c.1563C>G p.I521M | Missense Mutation (SNP) | VAF 30/252 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.146); catalogued as COSV65940559; called by muse, mutect2, varscan2
- SLC35F3 | c.240C>G p.I80M | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV64029529; called by muse, varscan2
- SLC39A8 | c.727C>T p.H243Y | Missense Mutation (SNP) | VAF 55/363 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.106); catalogued as COSV100765795; called by muse, mutect2, varscan2
- SPATA13 | c.317C>A p.S106Y | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as COSV57979010; called by muse, mutect2, varscan2
- SPATA17 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.837); catalogued as rs200104955, COSV65124724; called by muse, mutect2, varscan2
- SPATA6 | c.1198G>C p.E400Q | Missense Mutation (SNP) | VAF 35/235 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.97); catalogued as COSV100893066, COSV64057418; called by muse, mutect2, varscan2
- SPOP | c.408C>G p.F136L | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV61655149; called by muse, mutect2, varscan2
- TAF1L | c.3176G>C p.G1059A | Missense Mutation (SNP) | VAF 27/211 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV54267564; called by muse, mutect2, varscan2
- TBCC | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.148); catalogued as rs112578716; called by muse, mutect2, varscan2
- TET1 | c.4142G>A p.G1381E | Missense Mutation (SNP) | VAF 42/250 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.724); catalogued as COSV65387631; called by muse, mutect2, varscan2
- TRHR | c.635G>A p.G212E | Missense Mutation (SNP) | VAF 49/338 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV61237051; called by muse, mutect2, varscan2
- TRIM16L | c.705G>C p.Q235H | Missense Mutation (SNP) | VAF 13/170 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV67459332; called by muse, mutect2
- TTL | c.1102C>G p.Q368E | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.021); catalogued as rs549319256; called by muse, mutect2, varscan2
- TTN | c.8704G>A p.E2902K (on ENST00000591111; = p.E2856K on NM_003319.4) | Missense Mutation (SNP) | VAF 36/212 reads (17%) | PolyPhen possibly damaging (0.572); catalogued as COSV59914847; called by muse, mutect2, varscan2
- UBE2N | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as COSV58868402; called by muse, mutect2
- UGT3A1 | c.941A>G p.K314R | Missense Mutation (SNP) | VAF 49/360 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.033); catalogued as COSV57095702; called by muse, mutect2, varscan2
- WDR24 | c.2249C>G p.S750* (on ENST00000248142; = p.S620* on NM_032259.4) | Nonsense Mutation (SNP) | VAF 10/66 reads (15%) | catalogued as COSV99555360; called by muse, mutect2, varscan2
- ZNF365 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as COSV101237928; called by muse, mutect2, varscan2
- ZNF382 | c.1531C>T p.Q511* | Nonsense Mutation (SNP) | VAF 53/584 reads (9%) | catalogued as rs1568633040, COSV53090177; called by muse, mutect2
- ZNF791 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as COSV58480864; called by muse, mutect2, varscan2
- ABCB6 | c.2305C>G p.L769V | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ABCD4 | c.1554G>C p.W518C | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- ACVR2A | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ADO | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- AGBL1 | c.3324A>T p.P1108= | Splice Region (SNP) | VAF 48/156 reads (31%) | called by muse, mutect2, varscan2
- AKAP12 | c.723G>C p.E241D | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ALDH16A1 | c.2314C>G p.P772A | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ANK3 | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 34/255 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD40 | c.182C>G p.S61C | Missense Mutation (SNP) | VAF 34/420 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- ANO8 | c.1854C>G p.S618R | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- APOBEC2 | c.268C>A p.L90I | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- ARHGEF11 | c.1818G>C p.E606D | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- ARMC4 | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.411); called by muse, mutect2
- ARNT | c.1627G>C p.E543Q | Missense Mutation (SNP) | VAF 34/362 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- ARSK | c.1096G>C p.D366H | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- ATRAID | c.674C>G p.S225C (on ENST00000611786; = p.S112C on NM_016085.5) | Missense Mutation (SNP) | VAF 39/272 reads (14%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- BAZ2A | c.3433C>A p.P1145T | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- BCL9L | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 14/108 reads (13%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- BPIFB3 | c.524C>T p.S175L | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.259); called by muse, mutect2
- CAMSAP2 | c.3580C>T p.Q1194* (on ENST00000236925 / NM_001297707.2; = p.Q1183* on NM_203459.3) | Nonsense Mutation (SNP) | VAF 33/298 reads (11%) | called by muse, mutect2, varscan2
- CASP8AP2 | c.1090G>C p.E364Q | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- CAVIN2 | c.803G>C p.R268T | Missense Mutation (SNP) | VAF 67/429 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CCDC148 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 50/398 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- CCT8 | c.119C>G p.A40G | Missense Mutation (SNP) | VAF 52/315 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- CDC5L | c.1549G>A p.D517N | Missense Mutation (SNP) | VAF 42/399 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- CDCP2 | c.1174C>G p.Q392E | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDKN2A | c.457+3G>T | Splice Region (SNP) | VAF 67/198 reads (34%) | called by muse, mutect2, varscan2
- CECR2 | c.3952G>C p.D1318H (on ENST00000342247 / NM_001290047.2; = p.D1134H on NM_001290046.1) | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CELSR3 | c.740C>G p.S247* | Nonsense Mutation (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2, varscan2
- CHID1 | c.1041-1G>A p.X347_splice | Splice Site (SNP) | VAF 17/75 reads (23%) | called by muse, mutect2, varscan2
- CHML | c.721C>A p.Q241K | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- CLEC16A | c.1012C>G p.L338V | Missense Mutation (SNP) | VAF 38/226 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- CSMD2 | c.8158G>C p.E2720Q | Missense Mutation (SNP) | VAF 35/204 reads (17%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- CTPS2 | c.1102C>G p.L368V | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- CYP2A13 | c.998G>A p.R333K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2
- CYP2C8 | c.1070G>A p.R357K | Missense Mutation (SNP) | VAF 47/250 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DGKZ | c.2788G>C p.E930Q (on ENST00000454345 / NM_001105540.2; = p.E742Q on NM_003646.4) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- DPY19L3 | c.1446A>T p.R482S | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DRD5 | c.406G>T p.V136L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- DTX3L | c.963C>G p.F321L | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- EFR3B | c.1184C>T p.S395F | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EIF4A2 | c.667G>T p.E223* | Nonsense Mutation (SNP) | VAF 19/143 reads (13%) | called by muse, mutect2, varscan2
- EVPL | c.4505T>G p.L1502R | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- FAM149B1 | c.1534C>T p.Q512* | Nonsense Mutation (SNP) | VAF 23/226 reads (10%) | called by muse, mutect2, varscan2
- FAM178B | c.1738G>C p.E580Q (on ENST00000490605 / NM_001122646.3; = p.E20Q on NM_016490.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- FBN2 | c.5431G>A p.E1811K | Missense Mutation (SNP) | VAF 58/311 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FIGNL1 | c.1403C>T p.S468L | Missense Mutation (SNP) | VAF 38/218 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLG | c.3505C>A p.P1169T | Missense Mutation (SNP) | VAF 86/274 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- FRMD5 | c.707A>G p.K236R | Missense Mutation (SNP) | VAF 62/247 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- FRMPD1 | c.2894C>G p.S965* | Nonsense Mutation (SNP) | VAF 13/108 reads (12%) | called by muse, mutect2, varscan2
- GINS2 | c.33G>C p.E11D | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.283); called by muse, mutect2
- GMNN | c.427G>T p.E143* | Nonsense Mutation (SNP) | VAF 55/304 reads (18%) | called by muse, mutect2, varscan2
- GNLY | c.170C>G p.T57S | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- GPATCH2 | c.849G>C p.Q283H | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HECW1 | c.2485G>C p.E829Q | Missense Mutation (SNP) | VAF 46/262 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- HMMR | c.1123G>C p.E375Q | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- HNRNPA1 | c.133G>A p.V45I | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- IFI16 | c.117G>A p.M39I | Missense Mutation (SNP) | VAF 29/202 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- IGHD | c.429G>C p.K143N | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ISCU | c.319G>C p.E107Q (on ENST00000311893 / NM_213595.4; = p.E82Q on NM_014301.4) | Missense Mutation (SNP) | VAF 64/327 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ISY1-RAB43 | c.299G>A p.G100E | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.82); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KCNJ5 | c.1141C>G p.P381A | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- KIFBP | c.1178G>C p.R393T | Missense Mutation (SNP) | VAF 61/391 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- KIFC2 | c.157A>T p.T53S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- KPRP | c.287G>A p.G96D | Missense Mutation (SNP) | VAF 57/335 reads (17%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- KRTAP16-1 | c.909T>G p.C303W | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- LMBR1L | c.132C>G p.F44L | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- LNPK | c.64G>C p.D22H | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- LY9 | c.1920G>C p.Q640H | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- MALRD1 | c.6352C>T p.P2118S | Missense Mutation (SNP) | VAF 28/311 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- MARS2 | c.896C>G p.S299C | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- MCL1 | c.152G>A p.G51E | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- MGAM2 | c.2194G>C p.D732H | Missense Mutation (SNP) | VAF 55/241 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTMR9 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- MYH2 | c.2798A>C p.E933A | Missense Mutation (SNP) | VAF 59/397 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- NEFH | c.2803G>A p.D935N | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NEO1 | c.3411G>A p.K1137= | Splice Region (SNP) | VAF 24/68 reads (35%) | called by muse, mutect2, varscan2
- NES | c.4744G>C p.E1582Q | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- NUDT18 | c.529C>G p.L177V | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, varscan2
- NUF2 | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 51/421 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- NUGGC | c.2072G>A p.R691K | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NUP98 | c.1844A>G p.N615S | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.73); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OBSCN | c.6178G>A p.E2060K | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.769); called by muse, mutect2
- OR2L8 | c.451G>A p.G151S | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- OR2T10 | c.309C>G p.F103L | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ORC1 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 43/293 reads (15%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2, varscan2
- OTOG | c.5761A>C p.K1921Q | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PARD6G | c.681G>C p.K227N | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHA6 | c.2057C>T p.A686V | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDHGA4 | c.2346G>C p.Q782H | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- PCDHGA8 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 31/238 reads (13%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- PCM1 | c.1895G>C p.G632A | Missense Mutation (SNP) | VAF 45/292 reads (15%) | SIFT tolerated (0.77); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PDE6A | c.339C>G p.F113L | Missense Mutation (SNP) | VAF 37/253 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- PDE6A | c.99C>G p.I33M | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PHF10 | c.107C>G p.S36* | Nonsense Mutation (SNP) | VAF 61/287 reads (21%) | called by muse, mutect2, varscan2
- PIP5K1A | c.1669G>C p.E557Q (on ENST00000368888 / NM_001135638.2; = p.E544Q on NM_003557.3) | Missense Mutation (SNP) | VAF 29/286 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.046); called by muse, mutect2
- PITX2 | c.686C>T p.S229L (on ENST00000354925 / NM_001204397.1; = p.S236L on NM_000325.6) | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- POC5 | c.1343C>G p.S448C (on ENST00000428202 / NM_001099271.2; = p.S423C on NM_152408.2) | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- PRRC2B | c.1872_1875del p.P626Dfs*49 | Frame Shift Del (DEL) | VAF 11/67 reads (16%) | called by mutect2, pindel, varscan2
- RAB11FIP1 | c.1733C>T p.S578F | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- RAB11FIP1 | c.1586C>A p.S529Y | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- RABIF | c.109C>T p.L37F | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2
- RASSF10 | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RBMS1 | c.737G>C p.R246T | Missense Mutation (SNP) | VAF 35/236 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- RCOR1 | c.1084C>G p.L362V | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- REM2 | c.877C>G p.P293A | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- RET | c.3036G>C p.R1012S | Missense Mutation (SNP) | VAF 49/299 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF180 | c.1642G>C p.D548H | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RNF38 | c.1071+1_1071+2del p.X357_splice | Splice Site (DEL) | VAF 56/253 reads (22%) | called by mutect2, pindel, varscan2
- ROR1 | c.1691T>C p.L564P | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RPS15 | c.231G>C p.K77N | Missense Mutation (SNP) | VAF 29/243 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- RSU1 | c.256C>G p.Q86E | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- RTN1 | c.1826T>A p.L609Q | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- S100A7L2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 34/169 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- SBF1 | c.922G>C p.D308H | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- SCN3A | c.2833A>G p.I945V | Missense Mutation (SNP) | VAF 57/451 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SELENOO | c.1205G>C p.G402A | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SEMA6C | c.2237C>T p.P746L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.054); called by mutect2, varscan2
- SENP2 | c.1020G>C p.R340S | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- SERPINE1 | c.107C>G p.S36* | Nonsense Mutation (SNP) | VAF 16/120 reads (13%) | called by muse, mutect2, varscan2
- SERPINE1 | c.812C>G p.S271C | Missense Mutation (SNP) | VAF 17/281 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SHPRH | c.4574G>C p.R1525T (on ENST00000275233 / NM_001042683.3; = p.R1529T on NM_173082.3) | Missense Mutation (SNP) | VAF 45/295 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC27A2 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 66/204 reads (32%) | SIFT tolerated (0.79); PolyPhen benign (0.005); called by muse, varscan2
- SLC36A2 | c.84G>C p.K28N | Missense Mutation (SNP) | VAF 48/385 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLURP1 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 42/207 reads (20%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- SPI1 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- SRSF3 | c.229dup p.R77Kfs*8 | Frame Shift Ins (INS) | VAF 25/139 reads (18%) | called by mutect2, pindel, varscan2
- STOX1 | c.1267C>G p.Q423E | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYF2 | c.377-1G>C p.X126_splice | Splice Site (SNP) | VAF 23/145 reads (16%) | called by muse, mutect2, varscan2
- SYT14 | c.374C>A p.T125K | Missense Mutation (SNP) | VAF 65/512 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SZT2 | c.10152G>C p.K3384N (on ENST00000634258 / NM_001365999.1; = p.K3327N on NM_015284.4) | Missense Mutation (SNP) | VAF 31/216 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TARDBP | c.637C>G p.Q213E | Missense Mutation (SNP) | VAF 49/262 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- TENT5A | c.980C>T p.S327L | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- THOC1 | c.1469C>T p.S490L | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- THSD7B | c.2437G>C p.E813Q | Missense Mutation (SNP) | VAF 44/249 reads (18%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- TIGD5 | c.1252G>C p.E418Q | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- TMEM143 | c.211C>G p.R71G | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- TMEM179B | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- TMEM218 | c.155C>T p.S52L | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNFRSF10A | c.104G>A p.S35N | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TOGARAM1 | c.1976_1981del p.L659_P660del | In Frame Del (DEL) | VAF 8/58 reads (14%) | called by mutect2, pindel
- TRAF5 | c.-1-1G>C | Splice Site (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- TRIM33 | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.127); called by muse, varscan2
- TRIP12 | c.5906C>G p.S1969* | Nonsense Mutation (SNP) | VAF 18/158 reads (11%) | called by muse, mutect2, varscan2
- TTN | c.93730G>A p.E31244K (on ENST00000591111; = p.E23820K on NM_003319.4) | Missense Mutation (SNP) | VAF 10/55 reads (18%) | PolyPhen possibly damaging (0.6); called by muse, mutect2
- TTYH2 | c.1267G>A p.D423N | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- UBAP1 | c.1027del p.L343Sfs*71 | Frame Shift Del (DEL) | VAF 4/15 reads (27%) | called by mutect2, varscan2
- UNC80 | c.5317G>A p.E1773K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.969); called by muse, mutect2
- USP4 | c.1775C>T p.S592L | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- UTRN | c.5980G>C p.E1994Q | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- VSNL1 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.141); called by muse, varscan2
- VWA5B2 | c.3595C>T p.R1199W | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); called by muse, mutect2
- WDR19 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 31/211 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- ZCCHC8 | c.568G>C p.E190Q | Missense Mutation (SNP) | VAF 26/296 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- ZCRB1 | c.640G>C p.E214Q | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- ZDHHC2 | c.568G>C p.D190H | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZFHX3 | c.520C>G p.L174V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- ZNF189 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- ZNF274 | c.1138G>A p.D380N (on ENST00000610905; = p.D275N on NM_016324.3) | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF281 | c.2119G>C p.E707Q | Missense Mutation (SNP) | VAF 48/390 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ZNF484 | c.298G>C p.E100Q | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- ZNF582 | c.973C>T p.Q325* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2, varscan2
- ZNF780A | c.426G>A p.M142I | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- ZNFX1 | c.2844G>C p.K948N | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- ABLIM2 | c.1794C>G p.L598= (on ENST00000341937 / NM_001130084.2; = p.L508= on NM_032432.5) | Silent (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2
- ACSL6 | c.12C>T p.F4= | Silent (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2, varscan2
- ADAMTSL2 | c.1071G>T p.G357= | Silent (SNP) | VAF 23/115 reads (20%) | called by muse, mutect2, varscan2
- ANKRD13B | c.1779G>A p.A593= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as rs1395304157; called by muse, mutect2, varscan2
- ANKRD30A | c.3697A>C p.R1233= (on ENST00000611781; = p.R1177= on NM_052997.2) | Silent (SNP) | VAF 47/253 reads (19%) | called by muse, mutect2, varscan2
- ARF5 | c.223C>A p.R75= | Silent (SNP) | VAF 10/176 reads (6%) | catalogued as COSV99133941; called by muse, mutect2
- ARHGAP31 | c.1002C>G p.L334= | Silent (SNP) | VAF 34/312 reads (11%) | called by muse, mutect2, varscan2
- ARHGEF19 | c.2331C>T p.L777= | Silent (SNP) | VAF 10/37 reads (27%) | called by muse, mutect2, varscan2
- ATP6V0A2 | c.1245C>T p.F415= | Silent (SNP) | VAF 31/614 reads (5%) | catalogued as rs777398890, COSV57747513; called by muse, mutect2
- CACNA2D3 | c.924G>A p.L308= | Silent (SNP) | VAF 27/126 reads (21%) | called by muse, mutect2, varscan2
- CACNA2D4 | c.1443C>T p.H481= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as rs756007755, COSV54948153; called by muse, mutect2, varscan2
- CARNS1 | c.1023G>A p.V341= | Silent (SNP) | VAF 4/37 reads (11%) | called by muse, mutect2, varscan2
- CHD6 | c.5031G>A p.V1677= | Silent (SNP) | VAF 25/115 reads (22%) | called by muse, mutect2, varscan2
- CMBL | c.474C>G p.V158= | Silent (SNP) | VAF 34/126 reads (27%) | catalogued as rs1271254328; called by muse, mutect2, varscan2
- COL5A3 | c.4917G>C p.L1639= | Silent (SNP) | VAF 44/240 reads (18%) | called by muse, mutect2, varscan2
- DGKI | c.1218C>G p.V406= | Silent (SNP) | VAF 26/187 reads (14%) | called by muse, mutect2, varscan2
- DLGAP3 | c.861C>T p.F287= | Silent (SNP) | VAF 15/68 reads (22%) | called by muse, mutect2, varscan2
- FAM149A | c.1080C>T p.I360= (on ENST00000356371 / NM_001367768.2; = p.I69= on NM_015398.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as rs755856137, COSV99906580; called by muse, mutect2, varscan2
- FAM47C | c.93G>A p.A31= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as rs868908339, COSV63724809; called by muse, mutect2, varscan2
- FCGR3A | c.492C>T p.L164= | Silent (SNP) | VAF 55/576 reads (10%) | catalogued as COSV63458904; called by muse, mutect2
- FKRP | c.1464G>A p.L488= | Silent (SNP) | VAF 13/105 reads (12%) | catalogued as rs1196078520; called by muse, mutect2, varscan2
- FOXD3 | c.486G>T p.L162= | Silent (SNP) | VAF 58/189 reads (31%) | called by muse, mutect2, varscan2
- FSCN3 | c.1098G>A p.L366= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV56171745; called by muse, mutect2, varscan2
- GBA3 | c.744T>G p.T248= | Silent (SNP) | VAF 24/126 reads (19%) | called by muse, mutect2, varscan2
- GPR85 | c.162A>T p.A54= | Silent (SNP) | VAF 46/341 reads (13%) | called by muse, mutect2, varscan2
- GRIK4 | c.1338C>T p.G446= | Silent (SNP) | VAF 38/216 reads (18%) | called by muse, mutect2, varscan2
- HERC6 | c.1044C>G p.V348= | Silent (SNP) | VAF 14/195 reads (7%) | called by muse, mutect2
- HRNR | c.303G>C p.L101= | Silent (SNP) | VAF 22/230 reads (10%) | catalogued as rs773455208, COSV64255271, COSV64262925; called by muse, mutect2
- KIRREL3 | c.705C>T p.P235= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as rs749379208; called by muse, mutect2, varscan2
- KREMEN1 | c.1478G>A p.*493= | Silent (SNP) | VAF 28/152 reads (18%) | called by muse, mutect2, varscan2
- MAGEF1 | c.264G>T p.L88= | Silent (SNP) | VAF 22/167 reads (13%) | called by muse, mutect2, varscan2
- MED8 | c.300C>T p.F100= | Silent (SNP) | VAF 22/134 reads (16%) | called by muse, mutect2, varscan2
- MMACHC | c.9G>C p.P3= | Silent (SNP) | VAF 31/233 reads (13%) | called by muse, mutect2, varscan2
- MS4A1 | c.690G>C p.L230= | Silent (SNP) | VAF 26/205 reads (13%) | called by muse, mutect2, varscan2
- MYH8 | c.3480T>G p.T1160= | Silent (SNP) | VAF 29/104 reads (28%) | catalogued as COSV101238582; called by muse, mutect2, varscan2
- NAT16 | c.831C>G p.L277= | Silent (SNP) | VAF 23/49 reads (47%) | called by muse, mutect2, varscan2
- NEB | c.681G>C p.L227= | Silent (SNP) | VAF 26/191 reads (14%) | catalogued as COSV50817373, COSV99427478; called by muse, mutect2, varscan2
- NOA1 | c.624G>C p.A208= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV99950398; called by muse, mutect2
- NPAP1 | c.885G>A p.P295= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV61509195; called by muse, mutect2, varscan2
- NR4A3 | c.663C>T p.L221= | Silent (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2, varscan2
- NRXN3 | c.2304G>A p.G768= (on ENST00000335750 / NM_001330195.2; = p.G395= on NM_004796.6) | Silent (SNP) | VAF 14/138 reads (10%) | called by muse, mutect2, varscan2
- OPN4 | c.735C>T p.F245= | Silent (SNP) | VAF 15/111 reads (14%) | called by muse, mutect2, varscan2
- PCDH19 | c.822C>G p.V274= | Silent (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- PCDHGB6 | c.1065G>A p.Q355= | Silent (SNP) | VAF 34/176 reads (19%) | called by muse, mutect2, varscan2
- PHLPP2 | c.1416G>A p.L472= | Silent (SNP) | VAF 41/260 reads (16%) | called by muse, mutect2, varscan2
- PKDREJ | c.3288A>G p.R1096= | Silent (SNP) | VAF 26/169 reads (15%) | called by muse, mutect2, varscan2
- POTED | c.1500G>A p.Q500= | Silent (SNP) | VAF 17/136 reads (13%) | called by muse, mutect2, varscan2
- PRSS12 | c.351C>T p.P117= | Silent (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2, varscan2
- RAI2 | c.96G>A p.L32= | Silent (SNP) | VAF 12/98 reads (12%) | called by muse, mutect2, varscan2
- RFK | c.467G>A p.*156= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as rs751234028; called by muse, varscan2
- RIPOR2 | c.1500G>C p.L500= | Silent (SNP) | VAF 31/176 reads (18%) | called by muse, mutect2, varscan2
- SEZ6L2 | c.570G>A p.G190= (on ENST00000308713 / NM_001114099.3; = p.G120= on NM_012410.4) | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as rs755589385, COSV58098267, COSV58100714; called by muse, mutect2, varscan2
- SH2D5 | c.165G>A p.L55= | Silent (SNP) | VAF 11/119 reads (9%) | called by muse, mutect2
- SLC39A10 | c.1683C>G p.L561= | Silent (SNP) | VAF 24/241 reads (10%) | catalogued as rs778921146; called by muse, mutect2
- SLC6A3 | c.1779C>T p.Y593= | Silent (SNP) | VAF 75/297 reads (25%) | catalogued as rs141485913; called by muse, mutect2, varscan2
- SMTN | c.2589C>G p.A863= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV60782997; called by muse, mutect2, varscan2
- STAT4 | c.1827C>T p.F609= | Silent (SNP) | VAF 31/200 reads (16%) | called by muse, mutect2, varscan2
- STK11IP | c.1776G>A p.P592= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as rs534231346; called by muse, mutect2, varscan2
- STPG2 | c.105G>T p.A35= | Silent (SNP) | VAF 29/178 reads (16%) | called by muse, mutect2, varscan2
- SYCP2 | c.1093A>C p.R365= | Silent (SNP) | VAF 17/131 reads (13%) | called by muse, mutect2, varscan2
- TACC1 | c.345T>G p.S115= | Silent (SNP) | VAF 13/124 reads (10%) | called by muse, mutect2
- TMEM63B | c.1710G>A p.V570= | Silent (SNP) | VAF 13/46 reads (28%) | called by muse, mutect2, varscan2
- TMEM63C | c.177C>T p.L59= | Silent (SNP) | VAF 12/74 reads (16%) | called by muse, mutect2, varscan2
- TNNI2 | c.294G>A p.Q98= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as COSV53291199; called by muse, mutect2, varscan2
- VSNL1 | c.315C>T p.F105= | Silent (SNP) | VAF 34/282 reads (12%) | called by muse, varscan2
- XKR4 | c.1071C>T p.L357= | Silent (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- ZC3H4 | c.2457C>T p.S819= | Silent (SNP) | VAF 23/125 reads (18%) | called by muse, mutect2, varscan2
- ZNF439 | c.243C>T p.V81= | Silent (SNP) | VAF 37/188 reads (20%) | called by muse, mutect2, varscan2
- AC105942.1 | n.1040-1638G>A | Intron (SNP) | VAF 28/136 reads (21%) | called by muse, mutect2, varscan2
- ADAM1A | chr12:111901434 C>T | 3'Flank (SNP) | VAF 31/181 reads (17%) | called by muse, mutect2, varscan2
- ADAM23 | c.-38C>T | 5'UTR (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2, varscan2
- ANK3 | c.12596-409G>C | Intron (SNP) | VAF 28/274 reads (10%) | catalogued as rs756463710; called by muse, mutect2
- ANTXR1 | c.951+10410G>C | Intron (SNP) | VAF 12/109 reads (11%) | called by muse, mutect2
- AQP1 | c.385-254G>A | Intron (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
- ASTN1 | c.1120+254C>T | Intron (SNP) | VAF 30/284 reads (11%) | called by muse, mutect2, varscan2
- CCDC115 | chr2:130342165 A>T | 5'Flank (SNP) | VAF 10/51 reads (20%) | called by muse, mutect2, varscan2
- CCHCR1 | c.-51-446C>T | Intron (SNP) | VAF 36/161 reads (22%) | called by muse, mutect2, varscan2
- CDC5L | c.-31C>T | 5'UTR (SNP) | VAF 28/330 reads (8%) | catalogued as rs759264216; called by muse, mutect2
- CEP41 | c.*4448G>A | 3'UTR (SNP) | VAF 122/381 reads (32%) | called by muse, mutect2, varscan2
- CILK1 | c.*27C>T | 3'UTR (SNP) | VAF 19/104 reads (18%) | called by muse, mutect2, varscan2
- CRACR2B | c.459-16C>G | Intron (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2, varscan2
- CSTB | c.169-42G>A | Intron (SNP) | VAF 19/72 reads (26%) | called by muse, mutect2, varscan2
- CYTH4 | c.435-764G>C | Intron (SNP) | VAF 80/383 reads (21%) | called by muse, mutect2, varscan2
- DUSP3 | c.352+668C>A | Intron (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- DZANK1 | c.379-68C>G | Intron (SNP) | VAF 51/191 reads (27%) | called by muse, mutect2, varscan2
- EDN1 | c.-32G>C | 5'UTR (SNP) | VAF 63/313 reads (20%) | called by muse, mutect2, varscan2
- EFCAB13 | c.-59C>G | 5'UTR (SNP) | VAF 13/138 reads (9%) | called by muse, mutect2, varscan2
- EIF5B | c.-61G>A | 5'UTR (SNP) | VAF 10/91 reads (11%) | called by muse, mutect2, varscan2
- ELAVL4 | chr1:50106376 A>T | 5'Flank (SNP) | VAF 32/156 reads (21%) | catalogued as COSV100836570, COSV100836662; called by muse, mutect2, varscan2
- GJA3 | c.*6G>A | 3'UTR (SNP) | VAF 21/96 reads (22%) | called by muse, mutect2, varscan2
- GRIA1 | c.2385+765G>A | Intron (SNP) | VAF 34/162 reads (21%) | called by muse, mutect2, varscan2
- HSPH1 | chr13:31162031 G>C | 5'Flank (SNP) | VAF 13/89 reads (15%) | catalogued as rs1416882019; called by muse, mutect2, varscan2
- HTRA2 | c.906+10G>C | Intron (SNP) | VAF 20/174 reads (11%) | called by muse, mutect2, varscan2
- IFNGR2 | c.722-37G>A | Intron (SNP) | VAF 38/191 reads (20%) | catalogued as rs17885089; called by muse, mutect2, varscan2
- IL1B | c.597+32C>G | Intron (SNP) | VAF 41/235 reads (17%) | called by muse, mutect2, varscan2
- MICOS10 | c.64+11274C>G | Intron (SNP) | VAF 20/132 reads (15%) | called by muse, mutect2, varscan2
- MYLK | c.4619+28G>A | Intron (SNP) | VAF 28/120 reads (23%) | called by muse, mutect2, varscan2
- NBPF11 | c.*203G>C | 3'UTR (SNP) | VAF 70/525 reads (13%) | called by muse, mutect2, varscan2
- NDUFS7 | chr19:1383750 C>T | 5'Flank (SNP) | VAF 33/157 reads (21%) | catalogued as rs893203730; called by muse, mutect2, varscan2
- NELL1 | c.1549+55071C>T | Intron (SNP) | VAF 15/61 reads (25%) | called by muse, mutect2, varscan2
- NR5A2 | c.64+1153G>T | Intron (SNP) | VAF 32/246 reads (13%) | called by muse, mutect2, varscan2
- NRG2 | c.1190-4120G>A | Intron (SNP) | VAF 19/151 reads (13%) | called by muse, mutect2, varscan2
- NTNG2 | c.1054+742G>C | Intron (SNP) | VAF 13/100 reads (13%) | catalogued as rs778016269; called by muse, mutect2, varscan2
- NTRK1 | c.-19C>T | 5'UTR (SNP) | VAF 4/16 reads (25%) | catalogued as rs1190296938; called by mutect2, varscan2
- PHYKPL | c.60-263G>A | Intron (SNP) | VAF 31/233 reads (13%) | called by muse, mutect2, varscan2
- PLAGL2 | chr20:32189914 T>A | 3'Flank (SNP) | VAF 20/81 reads (25%) | called by muse, mutect2, varscan2
- PLOD1 | c.580-231C>T | Intron (SNP) | VAF 19/192 reads (10%) | catalogued as rs1186460137; called by muse, mutect2, varscan2
- POLR3D | chr8:22245039 G>T | 5'Flank (SNP) | VAF 4/20 reads (20%) | catalogued as rs764661279; called by mutect2, varscan2
- PPP4R1L | n.237G>C | RNA (SNP) | VAF 38/302 reads (13%) | called by muse, mutect2, varscan2
- PRC1 | c.*546G>C | 3'UTR (SNP) | VAF 55/139 reads (40%) | called by muse, mutect2, varscan2
- PRDM15 | c.-722C>G | 5'UTR (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2
- PTPRB | chr12:70520239 C>T | 3'Flank (SNP) | VAF 34/227 reads (15%) | called by muse, mutect2, varscan2
- RAB5IF | c.*119C>T | 3'UTR (SNP) | VAF 33/190 reads (17%) | called by muse, mutect2, varscan2
- RESP18 | c.*5G>A | 3'UTR (SNP) | VAF 19/166 reads (11%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159826 G>A | 5'Flank (SNP) | VAF 11/63 reads (17%) | catalogued as rs1567337561; called by muse, mutect2, varscan2
- RNF4 | c.9+20G>C | Intron (SNP) | VAF 14/90 reads (16%) | catalogued as rs759399441; called by muse, mutect2, varscan2
- SEC22A | c.-47G>A | 5'UTR (SNP) | VAF 36/160 reads (23%) | called by muse, mutect2, varscan2
- SHOC2 | c.-235+17100C>G | Intron (SNP) | VAF 88/287 reads (31%) | called by muse, mutect2, varscan2
- SIMC1 | c.-262G>C | 5'UTR (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2, varscan2
- SKA2P1 | n.389G>A | RNA (SNP) | VAF 30/140 reads (21%) | called by mutect2, varscan2
- SNRPG | c.32+429G>A | Intron (SNP) | VAF 20/184 reads (11%) | called by muse, mutect2, varscan2
- SNX21 | c.*719G>C | 3'UTR (SNP) | VAF 28/164 reads (17%) | called by muse, mutect2, varscan2
- SPAG11B | c.*103C>A | 3'UTR (SNP) | VAF 43/739 reads (6%) | called by muse, mutect2
- SPG7 | c.377-122G>T | Intron (SNP) | VAF 26/143 reads (18%) | called by muse, mutect2, varscan2
- TYK2 | c.2466+247G>C | Intron (SNP) | VAF 16/90 reads (18%) | catalogued as COSV53391740; called by muse, mutect2
- ZFAT | c.2475+568C>T | Intron (SNP) | VAF 20/111 reads (18%) | called by muse, mutect2
- ZNF395 | c.*21C>T | 3'UTR (SNP) | VAF 31/167 reads (19%) | called by muse, mutect2, varscan2
- ZSCAN32 | c.839-906C>T | Intron (SNP) | VAF 31/166 reads (19%) | catalogued as COSV59237637; called by muse, mutect2, varscan2
